Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5116, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5116-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, RIGHT, NEPHRECTOMY -

A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, WITH FOCAL CYSTIC CHANGE (see

comment).

B. FUHRMAN NUCLEAR GRADE IS 3 OF 4.

C. THE GREATEST DIAMETER OF THE NEOPLASM IS 10.5 cm.

D. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.

E. INVASION OF THE RENAL VEIN IS IDENTIFIED, AND TUMOR IS PRESENT AT THE RENAL VEIN MARGIN.

F. ALL REMAINING SURGICAL MARGINS ARE FREE OF THE NEOPLASM.

G. TUMOR IS SEEN INVOLVING THE RENAL PELVIS ADIPOSE TISSUE.

H. THE NON-NEOPLASTIC KIDNEY IS NOTABLE FOR MODERATE CHRONIC INFLAMMATION.

I. TNM STAGE: PT3b NX MX (see synoptic).

Source: NCI Genomic Data Commons file c31d4e48-981f-4ad1-8745-2bb238d2a31f (TCGA-B0-5116.D101A90F-788A-4220-8F4F-114B26F6BA7E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).